Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAF1, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAF1-01A (Primary Tumor).

Department of Pathology

ICD-O-3
Seminoma NOS 9061/3
Site: Testis NOS C62.9
JW 3/8/14

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Summary pathology report

Removal of abdominal testis on the right side; seminoma; diameter 6.5 cm; tumor confined to testis in available slides; angio-invasion present; invasion in rete testis present.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 6bd8820a-4211-4d74-a541-0f5064bc034a (TCGA-2G-AAF1.F4794A61-3289-4AC9-B32D-2A31BEBE9A0A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).